Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A1AF, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A1AF-01A (Primary Tumor).

[page 1 of 5]
ICD-0-3

Carcinoma, urothelial, NOS 8120/3

12/30/10

Site Code: bladder, NOS C67.9

h

SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

F

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Clinical Diagnosis & History:

Bladder cancer T2 disease.

Specimens Submitted:

- 1: SP: Bladder, urethra, uterus, ovaries, fallopian tubes, perivesicle nodes and anterior vaginal wall; radical cystectomy, total hysterectomy with bilateral salpingo-oophorectomy
- 2: SP: Lymph nodes, right pelvic; dissection
- 3: SP: Lymph nodes, left pelvic; dissection
- 4: SP: Ureter, distal, right; resection
- 5: SP: Ureter, right; resection

DIAGNOSIS:

1. SP: Bladder, urethra, uterus, ovaries, fallopian tubes, perivesicle nodes and anterior vaginal wall; radical cystectomy, total hysterectomy with bilateral salpingo-oophorectomy:

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Flat (in situ carcinoma)

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Identified

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Right ureter uninvolved

Left ureter uninvolved

Urethra uninvolved

Vascular Invasion:

Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Exhibiting ulceration
Exhibiting foreign body reaction

Female Genital Organs:
Show no pathologic abnormalities

Perivesical Lymph Nodes:
Not identified

The Pathologic Stage is (AJCC 2002):
pT3 (Invasion of perivesicle soft tissue)

2. SP: Lymph nodes, right pelvic; dissection:

Lymph Node Dissection:
Metastatic urothelial carcinoma
Number of lymph nodes examined: 6
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 1.1 cm.
Size of the largest metastatic focus : 0.5 cm.
Extranodal extension is identified

3. SP: Lymph nodes, left pelvic; dissection:

Lymph Node Dissection:
Metastatic urothelial carcinoma
Number of lymph nodes examined: 8
Number of lymph nodes with metastatic disease: 3
Size of the largest lymph node involved by tumor: 1.2 cm.
Size of the largest metastatic focus : 1.2 cm.
Extranodal extension is identified

4. Ureter, distal, right; resection:

- Partially denuded urothelium with mild to moderate urothelial atypia

5. SP: Ureter, right; resection:

- Segment of benign ureter

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result Spec
RECUT

al Stain

Comment

Gross Description:

1. The specimen is received fresh labeled, " Bladder, uterus, cervix, urethra, bilateral tubes and ovaries, anterior vaginal wall, perivesical lymph nodes". It consists of a cystohysterectomy with bilateral salpingo-oophorectomy specimen measuring 20 cm from superior to inferior, 10 cm laterally and 5.0 cm from anterior to posterior. The uterus measures 6.5 cm superior to inferior, 5.5 cm from cornu to cornu, and 3.0 from anterior to posterior. There is a subserosal calcified nodule at the fundus of the uterus measuring 1.1 cm in greatest dimension. The right ovary measures 2.3 x 1.5 x 1.5 cm. There is an adherent clear thin walled cyst measuring 4.2 x 3.8 x 2.5 cm. The right fallopian tube measures 7 cm in length with a normal fimbriated end and a pinpoint lumen.

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

The left ovary measures 2.5 x 1.8 x 1.5 cm. The left fallopian tube measures 7.5 cm in length with a normal fimbriated end and a pinpoint lumen. The right aspect of the bladder is inked green and the left aspect of bladder is inked blue. The uterus is inked black posteriorly. The cervix measures 2 cm in length. The ectocervix measures 4.5 cm in diameter. The bladder is opened along the anterior midline to reveal an oval, ulcerated, fungating lesion measuring 2.0 x 1.5 cm in the trigone area and the posterior wall. The lesion appears to be involving the both ureteral orifices. Both ureters are probed and appear blocked. The lesion is sectioned and revealed that the lesion is invading deeply into the muscularis layer. Extension to the inked fat is grossly not identified. The remaining bladder mucosa is pink and edematous. Discrete perivesical lymph nodes are grossly not identified. The entire lesion is submitted and the representative sections from the rest of the bladder are submitted. TPS is submitted. Photographs are taken.

Summary of sections:

RUM - right ureter margin
LUM - left ureter margin
UTHM - urethral margin
L - lesion
LUO - left ureter orifice
RUO - right ureter orifice
LP - left posterior wall
LA - left anterior wall
RP - right posterior wall
RA - right anterior wall
DOM - dome
F - perivesical fat
AC - anterior cervix
PC - posterior cervix
AEM - anterior endometrium
PEM - posterior endometrium
RO - right ovary and cyst
RT - right tube
LO - left ovary
LT - left tube
VCM - vaginal cuff margin

2.) The specimen is received in formalin, labeled "Right pelvic lymph nodes" and consists of a 3.8 x 3.0 x 1.0 cm aggregate of lobulated, focally hemorrhagic, yellow adipose, which is sectioned to reveal seven, firm, tan-pink lymph nodes, ranging from 0.3 to 2.2 cm, in greatest dimension. The larger lymph nodes are bisected and all lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes
BLN - bisected lymph nodes

3.) The specimen is received in formalin, labeled "Left pelvic lymph nodes" and consists of a 5.3 x 3.8 x 1.5 cm aggregate of lobulated, focally hemorrhagic, yellow adipose, which is sectioned to reveal nine, firm, tan-pink lymph nodes, ranging from 0.3 to 2.0 cm, in greatest dimension. The larger lymph nodes are bisected and all lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes
BLN - bisected lymph nodes

4.) The specimen is received in formalin, labeled "Right distal ureter" and consists of an unoriented, 0.3 cm length and 0.6 cm in diameter portion of ureter, which is submitted in toto.

Summary of sections:

RDU - right distal ureter

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

5.) The specimen is received in formalin, labeled "Right ureter, clip and is proximal margin" and consists of an oriented, 2.3 cm in length and 0.4 cm in diameter portion of ureter surrounded by a 0.4 cm thick adipose tissue. A clip marks the proximal margin, which is inked in blue and the opposite margin is inked in black. The specimen is serially sectioned from the proximal margin to the opposite margin and is entirely submitted in sequential order.

Summary of sections:

PM — proximal margin

SS — sequential sections

OM — opposite margin

Summary of Sections:

Part 1: SP: Bladder, urethra, uterus, ovaries, fallopian tubes, perivesicle nodes and anterior vaginal wall; radical cystectomy, total hysterectomy with bilateral salpingo-oophorectomy

Block	Sect. Site	PCs
1	AC	1
1	AEM	1
1	DOM	1
1	F	1
5	L	5
1	LA	1
1	LO	1
1	LP	1
1	LT	1
1	lum	1
1	PC	1
1	PEM	1
1	RA	1
1	RO	1
1	RP	1
1	RT	1
1	rum	1
1	RUM2	1
1	RUO	1
1	uthm	1
1	VCM	1

Part 2: SP: Lymph nodes, right pelvic; dissection

Block	Sect. Site	PCs
3	BLN	6
1	LN	4

Part 3: SP: Lymph nodes, left pelvic; dissection

Block	Sect. Site	PCs
7	BLN	14
1	LN	2

Part 4: SP: Ureter, distal, right; resection

Block	Sect. Site	PCs
1	RDU	1

Part 5: SP: Ureter, right; resection

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Block	Sect. Site	PCs
1	OM	1
1	PM	1
1	SS	3

Source: NCI Genomic Data Commons file 19eb9abb-0c7c-4d65-a929-e6c5c40338a4 (TCGA-DK-A1AF.587A4629-6ADF-46A3-9F02-A167120286D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).